Somatic mutation profile of tumor specimen BA2714D (aliquot aq-BA2714D) from BEATAML1.0 case 2366, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 60.6 years (22,149 days).
Specimen BA2714D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ae99a15a-0146-45e1-b9ca-7a21b5360e92.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2428D (Solid Tissue Normal), aliquot aq-BA2428D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/48ea2346-3aca-45ea-a319-78e81bc8e0eb

The open-access MAF lists 16 somatic variants for this specimen: 9 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 5, RNA 1, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.1471G>C p.V491L | Missense Mutation (SNP) | VAF 26/69 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.077); catalogued as COSV54042664, COSV54046758; called by muse, mutect2, varscan2
- KRTAP26-1 | c.532G>A p.V178I | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT tolerated (0.62); PolyPhen benign (0.047); catalogued as COSV62129586; called by mutect2, varscan2
- PDZRN4 | c.2369C>T p.S790L (on ENST00000402685 / NM_001164595.2; = p.S532L on NM_013377.4) | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.035); catalogued as COSV100115621; called by muse, mutect2
- ARMCX5-GPRASP2 | c.826C>A p.Q276K | Missense Mutation (SNP) | VAF 3/47 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.115); called by muse, mutect2
- CDH7 | c.779C>A p.P260H | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- GPR84 | c.32G>T p.C11F | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2
- TBXA2R | c.953G>T p.R318L | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2
- WT1 | c.1147_1156del p.Y383Afs*51 | Frame Shift Del (DEL) | VAF 56/222 reads (25%) | called by pindel, varscan2
- ZNF407 | c.2485A>G p.K829E | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated (0.33); PolyPhen benign (0.194); called by muse, varscan2
- AGMAT | c.552G>T p.V184= | Silent (SNP) | VAF 6/66 reads (9%) | called by muse, mutect2
- KCNA3 | c.369C>T p.C123= | Silent (SNP) | VAF 33/79 reads (42%) | catalogued as COSV63902128; called by muse, mutect2, varscan2
- KLHL36 | c.198G>T p.V66= | Silent (SNP) | VAF 59/132 reads (45%) | called by muse, mutect2, varscan2
- RUBCNL | c.1101G>T p.L367= | Silent (SNP) | VAF 5/87 reads (6%) | catalogued as rs1472410153; called by muse, mutect2
- SUFU | c.895C>A p.R299= | Silent (SNP) | VAF 4/45 reads (9%) | called by muse, mutect2
- SLCO2A1 | chr3:133928498 C>A | 3'Flank (SNP) | VAF 3/33 reads (9%) | called by muse, mutect2
- TPRXL | n.1156T>C | RNA (SNP) | VAF 4/40 reads (10%) | catalogued as rs1369917849; called by muse, mutect2
